Gene-level copy-number profile of tumor specimen TCGA-A2-A0SY-01A from TCGA case TCGA-A2-A0SY, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 62.8 years (22,928 days).
Specimen TCGA-A2-A0SY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.b322940e-f03c-46f9-9dd4-f027089d5b40.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A2-A0SY-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/251ac37b-69a5-4866-ac5b-be853d5e4314

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,167; copy number 2: 51,917; copy number 3: 4,536; copy number 6: 18; copy number 7: 121; copy number 10: 60.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A2-A0SY-01A-31D-A087-01): tumor purity 0.65, ploidy 2.03, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 199 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:38,324,571–41,425,049, 180 genes, copy number 6–10 (within-gene range 1–10) (broad region; genes not listed).
- chr17:41,665,566–42,025,644, 19 genes, copy number 7: AC130686.1, EIF1, GAST, HAP1, RNA5SP442, RN7SL399P, JUP, P3H4, FKBP10, NT5C3B, KLHL10, AC125257.1, KLHL11, ACLY, AC125257.2, TTC25, CNP, DNAJC7, NKIRAS2.

Autosomal genes at a single copy (total copy number 1): 3,167. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
